Somatic mutation profile of tumor specimen 0DUNPB from CCDI case PBCKMI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,240 days).
Specimen 0DUNPB: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c3305bf-0ce5-45c2-9731-df56d5621d90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUETH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8a110a1-d3d0-4aaf-9fcd-9bf6f71de97a

The open-access MAF lists 9 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, 3'UTR 3, 5'UTR 1, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 26/558 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 20/328 reads (6%) | catalogued as rs1167537044; called by muse, mutect2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 9/78 reads (12%) | called by mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 30/289 reads (10%) | called by muse, varscan2
- CYB5R1 | c.238+77C>A | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- NSFL1C | c.786-60T>A | Intron (SNP) | VAF 10/78 reads (13%) | called by muse, varscan2
- NUP214 | c.3659+27C>A | Intron (SNP) | VAF 14/267 reads (5%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/238 reads (11%) | called by muse, varscan2
- SIAH1 | c.*157G>A | 3'UTR (SNP) | VAF 6/64 reads (9%) | called by mutect2, varscan2
